Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IU, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IU-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Corrected Report Comment

The reason for the corrected report is to change the lymph node count from 1 to 24 to 2 to 25, and also the synoptic report will have to be corrected.

Final Diagnosis

- A. HEAD OF PANCREAS, PORTION OF DUODENUM, PORTION OF STOMACH AND GALLBLADDER, PANCREATICO DUODENECTOMY AND CHOLECYSTECTOMY:
Pancreatic ductal adenocarcinoma, poorly-differentiated, with focal clear cell differentiation.
Carcinoma extends into the posterior retroperitoneal soft tissue.
The common bile duct, duodenal, gastric, superior mesenteric artery margin, portal groove, and posterior surface are all free of carcinoma.
Metastatic carcinoma to 2 of 25 lymph nodes (2/25).
Chronic cholecystitis and cholelithiasis.
See synoptic report.

- B. PANCREAS, FINAL MARGIN, RESECTION:
Pancreatic parenchyma, negative for carcinoma and intraepithelial neoplasia.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Key Pathological Findings

A: Pancreas Exocrine

SPECIMEN:

Head of pancreas
Duodenum
Stomach
Common bile duct
Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension of solid component: 4.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

ICD-O 3

Adenocarcinoma, duct NOS
8500/3

Site: Pancreas head
C25.0

4/16/14

[page 2 of 3]
Tumor invades retroperitoneal soft tissue

MARGINS:
Margins uninvolved by invasive carcinoma

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
No prior treatment

LYMPH-VASCULAR INVASION:
Present

PERINEURAL INVASION:
Present

TNM DESCRIPTORS:
Not applicable

PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

HISTOLOGIC PATTERNS:
Clear cell

REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 25
Number involved: 2

DISTANT METASTASIS (pM):
Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 2)
Squamous metaplasia

CLINICAL HISTORY:
Not specified

Specimen(s) Received

- A. WHIPPLE FS
- B. PANCREATIC MARGIN FS

Clinical History

PANCREATIC CA

Preoperative Diagnosis

Pancreatic cancer.

Intraoperative Consultation

FSA1. WHIPPLE:
Bile duct margin, no evidence of malignancy.

FSB1. PANCREATIC MARGIN:
No evidence of malignancy.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr

[page 3 of 3]
I, _____ M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for frozen section analysis labeled "stomach, pancreas, bile duct, duodenum, gallbladder." The specimen consists of a resected head of pancreas (5.0 x 3.0 x 1.5 cm), portion of stomach (3.0 cm on the lesser curvature and 6.5 cm on the greater curvature), duodenum (11.0 cm in length and 5.0 cm in circumference), and gallbladder (8.5 x 4.0 x 3.5 cm).

The pancreatic margin of resection is removed and submitted tangentially. The portal vein groove is marked with yellow ink, removed and entirely submitted perpendicularly. The superior mesenteric artery margin of resection is marked with black ink, totally removed and entirely submitted perpendicularly. The retroperitoneal surface is marked with blue ink and is entirely submitted perpendicularly. A palpable pancreatic mass is appreciated. The pancreatic duct is probe patent for approximately 5 mm and is totally obstructed due to the presence of a firm, gray yellow, ill-defined pancreatic mass (4.0 x 3.0 x 2.0 cm). The mass is approximately 5 mm from the pancreatic margin of resection and grossly abuts the portal vein groove and the superior mesenteric artery margin of resection. Grossly the mass appears to involve the wall of the common bile duct but does not appear to involve the Ampulla of Vater or duodenum. The remainder of the pancreatic parenchyma is grossly unremarkable. The duodenum and gastric mucosa exhibits normal mucosal folds with no gross evidence of nodularity or polypoid lesions. A catheter is inserted in the common bile duct. The gallbladder is filled with a small amount of green viscous bile. There is 1 green-yellow calculi present measuring 1.5 x 1.0 x 1.0 cm. The mucosal surface is green yellow and velvet-like. The wall of the gallbladder ranges from 0.1 cm to 0.3 cm in thickness. On gross examination, the gallbladder is free of tumor. A section of the adjacent adipose tissue isolates 2 gray-tan, irregular lymph nodes measuring 1.5 cm in greatest dimension. The lymph nodes are isolated at the pancreas. A representative frozen section is taken and submitted as FSA1 and submitted as bile duct. Permanent sections are submitted as:

- A2: Mirror image of tumor submitted to tissue bank
- A3: Tangential pancreatic margin of resection
- A4: Perpendicular portal vein groove
- A5-A6: Perpendicular superior mesenteric artery margin of resection
- A7-A8: Perpendicular retroperitoneal surface
- A9: Tangential gastric margin of resection
- A10: Tangential duodenal margin of resection
- A11: Tumor showing its relationship to the pancreatic duct
- A12-A13: Tumor showing its relationship to the common bile duct
- A14: Ampulla of Vater
- A15: Tumor showing its relationship to the duodenum
- A16-A17: Additional sections of tumor showing its relationship to adjacent tumor
- A18: Grossly unremarkable pancreatic parenchyma
- A19: Grossly unremarkable gastric mucosa
- A20: Grossly unremarkable duodenal mucosa
- A21: Grossly unremarkable gallbladder
- A22: Two lymph nodes, peripancreatic
- A23: Entire adipose tissue adjacent to pancreas
- A24-A27: Entire adipose tissue attached to lesser curvature
- A28-A35: Entire adipose tissue attached to greater curvature

B. Specimen B is received fresh for frozen section analysis labeled "pancreatic margin." The specimen consists of a 2.5 x 1.5 x 0.5 cm, moderately-firm, brown-tan, irregular fragment of tissue which is entirely submitted tangentially for frozen section as FSB1.

Source: NCI Genomic Data Commons file d92eddcc-f553-4ac9-a6de-4189dfc05ff1 (TCGA-3A-A9IU.49937937-79B1-4723-9E00-9EDD2F8707BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).